Surgical pathology report (de-identified scan), TCGA case TCGA-44-3396, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-3396-01A (Primary Tumor).

[page 1 of 5]
SPECIMEN

- A. Pericardial reflection node
- B. Right upper and middle lobe
- C. Lymph node level 11
- D. Lymph node 4R
- E. Lymph node 2R
- F. Lymph node level 9

CLINICAL NOTES

Non-small cell lung cancer

FROZEN SECTION DIAGNOSIS

- A) Lymph node, pericardial reflection node, excision - Metastatic non small cell carcinoma.

GROSS DESCRIPTION

A. Received fresh for frozen section labeled "pericardial reflection node" are irregularly shaped fragments of tan tissue that

measure 0.6 x 0.6 x 0.4 cm in aggregate dimension. The tissue is entirely frozen.

B. Received fresh, subsequently fixed and inflated with formalin labelled "bilobe right upper and middle lobe" is

a

14.0 x 12.0 x 5.7 cm portion of lung which is grossly consistent with the upper and middle lobe of the right lung. The pleural is violaceous smooth glistening with black stippling present showing a 3.0 cm umbilication at the fissure of the middle and upper lobe. This focus is inked and the specimen is sectioned to show a large white-gray firm mass which is 5.5 x 5.0 x 3.7 cm. The tumor is contiguous with the umbilication and is also present at the base of the middle lobe. There are staples present at this area. This

area

is inked and on sectioning shows no discrete tumor invading the stapled tissue. The remainder of the parenchyma is red-brown and fleshy. Few hilar nodes are grossly identified. The tumor comes within 1.5 cm of the bronchial margin. Representative sections of

[page 2 of 5]
GROSS DESCRIPTION

the specimen are submitted as follows:

BLOCK SUMMARY: 1 - bronchial and vascular margins; 2-5 - representative section of tumor to umbilication and normal; 6 - representative section of tumor to base at stapled aspect of middle lobe; 7 - tumor to bronchus; 8 - representative normal; 9-10. possible hilar lymph node (block 10 is bisected). RS-10

C. Received fresh subsequently fixed in formalin labeled "lymph node level 11" is a 1 x 0.5 x 0.4 cm black red irregular soft tissue fragment which is entirely submitted in one cassette. AS-1.

D. Received fresh subsequently fixed in formalin labeled "lymph node 4R" are two red black pink irregular soft tissue fragments which are 0.6 cm each in greatest dimension. The specimens are entirely submitted in one cassette. AS-1.

E. Received fresh subsequently fixed in formalin labeled "lymph node 2R" are multiple pink yellow black irregular soft to hard tissue fragments which have an aggregate measurement of 2.2 x 1.5 x 0.7 cm. The specimens are entirely submitted in one cassette. AS-1.

F. Received fresh subsequently fixed in formalin labeled "lymph node level 9" is a 2 x 0.7 x 0.3 cm pink black irregular soft tissue fragment which is entirely submitted in one cassette. AS-1.

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma.

Histologic grade: Poorly differentiated.

Primary tumor (pT): The tumor measures 5.5 cm. in dimension and is present within less than 0.2 cm. of the bronchial margin of excision, PT2.

Margins of resection: Invasive carcinoma is present in soft tissue

[page 3 of 5]
MICROSCOPIC DESCRIPTION

of the lung within 0.2 cm. of the bronchial margin of excision.

Direct extension of tumor: Tumor shows multifocal areas of extension up to and focally into the pleural but is not identified on the pleural surface.

Vessel invasion: Present.

Regional lymph nodes (pN): Tumor shows involvement of hilar lymph nodes which appears to be direct extension, although metastases can not be excluded. Metastatic carcinoma is identified in a pericardial reflection node, pN2.

Distant metastasis (pM): pMx.

14x1, 3x5, 5x1

DIAGNOSIS

- A. Lymph node, pericardial reflection node, excision - One lymph node positive for metastatic carcinoma (1/1).
- B. Lung, right upper and middle lobe, excision - Invasive poorly differentiated adenocarcinoma (see tumor characteristics in the lung resection template in the microscopic description).
- C. Lymph node, level 11, excision - One lymph node negative for metastatic carcinoma (0/1).
- D. Lymph node, level 4R, excision - Two lymph nodes negative for metastatic carcinoma (0/2).
- E. Lymph node, level 2R, excision - Fragments of lymph node negative for metastatic carcinoma.
- F. Lymph node, level 9, excision - One lymph node negative for metastatic carcinoma (0/1).
-

--- End Of Report ---

[page 4 of 5]
E. Received fresh subsequently fixed in formalin labeled
"level 5" is a 1.5 x 1.0 x 0.7 cm. black pink tan
irregular
rubbery tissue fragment. The specimen is bisected to show a white
firm rubbery nodule which is entirely submitted in one cassette.
AS-1

F. Received fresh and subsequently fixed in formalin
labeled "level 4 is a 0.5 x 0.3 x 0.3 cm pink-red
irregular
soft tissue fragment which is entirely submitted in one cassette.
AS-1.

MICROSCOPIC DESCRIPTION

A. The following template applies to the left lower lobe
wedge resection:

Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Primary tumor (pT): 1.7 cm (pT1)
Margins of resection: Uninvolved
Venous (large vessel) invasion: Not identified
Arterial (large vessel) invasion: Not identified
Lymphatic (small vessel) invasion: Not identified

MICROSCOPIC DESCRIPTION

Regional lymph nodes (pN): See specimen E below
Distant metastasis (pM): Cannot be evaluated by this specimen
(pMX)
Other findings: None.

B. The following template applies to the left upper lobe
wedge resection:

Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Primary tumor (pT): 1.8 cm (pT1)
Margins of resection: Uninvolved
Direct extension of tumor: Tumor invades the visceral pleura
Venous (large vessel) invasion: Not identified
Arterial (large vessel) invasion: Not identified
Lymphatic (small vessel) invasion: Not identified
Regional lymph nodes (pN): See specimen E below
Distant metastasis (pM): Cannot be evaluated by this specimen
(pMX)
Other findings: None.

[page 5 of 5]
C. The level 7 lymph node demonstrates no evidence of metastasis in one node.

with D. The level 6 lymph node demonstrates two lymph nodes
no evidence of metastatic disease.

E. The level 5 lymph node demonstrates metastatic poorly differentiated carcinoma involving one lymph node. The size of the metastasis is 1.5 cm.

F. The level 4 lymph node demonstrates no evidence of metastasis in one lymph node.

MICROSCOPIC DESCRIPTION

14x2, 4x2, 3x4

DIAGNOSIS

- A. Lung, left lower lobe, wide resection:
- Poorly differentiated adenocarcinoma, 1.7 cm, surgical margins uninvolved.
- B. Lung, left upper lobe, wedge resection:
- Poorly differentiated adenocarcinoma, 1.8 cm, surgical margins uninvolved.
- C. Level 7 lymph node, resection:
- No evidence of metastasis to one lymph node (0/1).
- D. Level 6 lymph node, resection:
- No evidence of metastasis to two lymph nodes (0/2).
- E. Level 5 lymph node, resection:
- Metastatic adenocarcinoma involving one lymph node, size of metastasis 1.5 cm.
- F. Level 4 lymph node, resection:
- No evidence of metastasis to one node (0/1).

Source: NCI Genomic Data Commons file 80798b0c-8f68-490f-8b32-5c597df69501 (TCGA-44-3396.6A7EC9E8-EA86-4C3B-9D0E-9564E41311B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).